Somatic mutation profile of tumor specimen TCGA-17-Z026-01A (aliquot TCGA-17-Z026-01A-01W-0746-08) from TCGA case TCGA-17-Z026, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z026-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a73bcae9-ebcc-4ac4-8390-a454eaa9e7c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z026-11A (Solid Tissue Normal), aliquot TCGA-17-Z026-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4d85984-3b12-401e-b3be-9534c044462e

The open-access MAF lists 1,031 somatic variants for this specimen: 763 protein-altering or splice-affecting, 242 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 658, Silent 242, Nonsense Mutation 75, Splice Site 15, Intron 14, RNA 8, Frame Shift Del 7, Frame Shift Ins 3, 5'UTR 2, Nonstop Mutation 2, 3'UTR 2, Splice Region 2.

Variants (750 of 1,031; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRNP | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.832); catalogued as rs398122370, CM001315; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | hotspot (GDC flag); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; called by muse, mutect2, varscan2
- A2ML1 | c.3145C>T p.Q1049* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs368566164; called by muse, mutect2, varscan2
- ABCA8 | c.3101T>G p.V1034G | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV52201752; called by muse, mutect2, varscan2
- ABCC9 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs945226728; called by muse, mutect2
- ABCG4 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs780697967; called by muse, mutect2, varscan2
- ADAMTS16 | c.2309G>C p.G770A | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56982813, COSV56997422; called by muse, mutect2, varscan2
- ADGRG4 | c.5785C>G p.L1929V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV54952384; called by muse, mutect2, varscan2
- ADGRG7 | c.876A>G p.I292M | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs1012327046; called by muse, mutect2
- AKAP12 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1247867265, COSV53571746; called by muse, mutect2
- AL592490.1 | c.2855G>C p.*952Sext*6 | Nonstop Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV101308216; called by muse, mutect2
- ALDH8A1 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55641342; called by muse, mutect2
- ANK1 | c.5318C>A p.A1773D | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); catalogued as rs772756792; called by muse, varscan2
- ANKFY1 | c.2032G>T p.G678* (on ENST00000341657 / NM_001330063.2; = p.G679* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 37/141 reads (26%) | catalogued as COSV100492166; called by muse, mutect2, varscan2
- AP1G2 | c.1876C>G p.L626V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV55337761; called by muse, mutect2, varscan2
- ARGFX | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 28/562 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.446); catalogued as rs1260192918; called by muse, mutect2
- ARGFX | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV100544262, COSV57682248; called by muse, mutect2
- ARHGAP33 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV50142818; called by muse, mutect2, varscan2
- ARMT1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.201); catalogued as rs563766286; called by muse, mutect2, varscan2
- ASB2 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs892432432; called by muse, mutect2, varscan2
- ATF7 | c.1420G>A p.E474K (on ENST00000548446 / NM_001366555.2; = p.E463K on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV60643264; called by muse, mutect2
- BAZ2B | c.4831G>T p.G1611C | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394677926; called by muse, mutect2, varscan2
- BCL11A | c.577C>G p.L193V (on ENST00000335712 / NM_001365609.1; = p.L227V on NM_018014.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV59635749; called by muse, mutect2, varscan2
- BCL6 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.971); catalogued as rs1488877472; called by muse, mutect2
- BIRC6 | c.6153G>T p.Q2051H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.259); catalogued as rs1178746267; called by muse, mutect2, varscan2
- BMP2K | c.2644C>T p.Q882* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | catalogued as COSV55009682; called by muse, mutect2, varscan2
- BNC1 | c.2661G>T p.M887I | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99077050; called by muse, mutect2, varscan2
- BRCA1 | c.5437G>C p.D1813H | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV58803580; called by muse, mutect2
- BRF2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs373464922; called by muse, mutect2, varscan2
- BTN2A1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.343); catalogued as rs1487252918; called by muse, mutect2, varscan2
- C2orf16 | c.2638T>A p.W880R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs777006672; called by muse, mutect2, varscan2
- C8orf37 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54412487; called by muse, mutect2
- C9orf43 | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV55912965; called by muse, mutect2
- CACNA1A | c.3880G>C p.E1294Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64189912; called by muse, mutect2
- CASP14 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 56/381 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV55667021; called by muse, mutect2, varscan2
- CASP8 | c.999C>G p.I333M (on ENST00000432109 / NM_033355.3; = p.I350M on NM_001228.4) | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51845155; called by muse, mutect2
- CCDC146 | c.2180T>A p.L727Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99592566; called by muse, mutect2
- CCDC181 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 54/254 reads (21%) | catalogued as rs1214328764, COSV63157408; called by muse, mutect2, varscan2
- CCDC54 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV53758095, COSV53758684, COSV99660233; called by muse, mutect2, varscan2
- CCR6 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.714); catalogued as rs1333636019; called by muse, mutect2
- CCT4 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101075127; called by muse, mutect2
- CD274 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV67501246; called by muse, mutect2, varscan2
- CD80 | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 20/178 reads (11%) | catalogued as COSV99958214; called by muse, mutect2, varscan2
- CDH11 | c.2121del p.L708Sfs*48 | Frame Shift Del (DEL) | VAF 20/155 reads (13%) | catalogued as COSV51770452; called by pindel, varscan2
- CDH12 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772189448, COSV66392948; called by muse, mutect2, varscan2
- CDH8 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs868451941; called by muse, mutect2, varscan2
- CDKAL1 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs1259941667; called by muse, mutect2
- CDKN2A | c.311T>A p.L104Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58688932, COSV58701895; called by muse, mutect2
- CDR1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267606368, COSV65164044; called by muse, mutect2, varscan2
- CEP112 | c.1504G>T p.A502S | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1453850647; called by muse, mutect2
- CHI3L1 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV55137265; called by muse, mutect2, varscan2
- CLDN17 | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV54522241, COSV54523253; called by muse, mutect2
- CLINT1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99754324; called by muse, mutect2, varscan2
- CLSTN2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 17/462 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV101515914; called by muse, mutect2
- CNGA2 | c.715del p.D239Tfs*62 | Frame Shift Del (DEL) | VAF 41/92 reads (45%) | catalogued as COSV61704007; called by mutect2, pindel, varscan2
- CNGA3 | c.1625G>T p.S542I | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1405438176, COSV99736267; called by muse, mutect2, varscan2
- CNTNAP5 | c.2300C>A p.T767N | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs1194493497; called by muse, mutect2, varscan2
- COG7 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1240636596; called by muse, mutect2, varscan2
- COL2A1 | c.3424C>T p.P1142S | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1055360917; called by muse, mutect2, varscan2
- COL5A3 | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs541298042; called by muse, mutect2, varscan2
- CPQ | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV99611670; called by muse, mutect2
- CSMD3 | c.4736C>A p.P1579H (on ENST00000297405 / NM_001363185.1; = p.P1475H on NM_052900.3) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52198184, COSV52274800; called by muse, mutect2, varscan2
- CTNND2 | c.2730C>A p.C910* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV100479720, COSV58872802; called by muse, mutect2, varscan2
- CUL5 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1243892491; called by muse, mutect2, varscan2
- CUZD1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs369603738; called by muse, mutect2, varscan2
- CYP20A1 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100619068; called by muse, mutect2, varscan2
- CYP4F11 | c.1390G>T p.G464W | Missense Mutation (SNP) | VAF 151/370 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56127853; called by muse, mutect2, varscan2
- DCDC1 | c.3502G>C p.E1168Q (on ENST00000597505 / NM_001367979.1; = p.E275Q on NM_020869.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as rs375684196; called by mutect2, varscan2
- DDX21 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as COSV62555676; called by muse, varscan2
- DEFA4 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52404561; called by muse, mutect2
- DGKA | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs774086426, COSV59388559; called by muse, mutect2, varscan2
- DHX30 | c.762G>C p.Q254H (on ENST00000445061 / NM_138615.3; = p.Q215H on NM_014966.3) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100820063; called by muse, mutect2
- DIAPH2 | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100235187, COSV100235956; called by muse, mutect2, varscan2
- DMBT1 | c.6588C>A p.F2196L (on ENST00000338354 / NM_001377530.1; = p.F1439L on NM_004406.3) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV57532770; called by muse, mutect2
- DMD | c.953C>G p.P318R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV55895535; called by muse, mutect2, varscan2
- DNAH3 | c.5345C>A p.S1782* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as COSV54532469; called by muse, mutect2, varscan2
- DNAJC14 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV57912186, COSV57914103; called by muse, mutect2
- DNMBP | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100144224; called by muse, mutect2
- DOCK8 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781538473, COSV66633648; called by muse, varscan2
- DPEP3 | c.1250C>A p.A417E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV52051152; called by muse, mutect2
- DSP | c.8576C>G p.S2859C | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs989922991, COSV100672898; called by muse, mutect2
- ECT2 | c.2432C>T p.S811F (on ENST00000392692 / NM_001349098.2; = p.S780F on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1336091183; called by muse, mutect2, varscan2
- EGFR | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51770611, COSV51785698; called by muse, mutect2, varscan2
- EPHA3 | c.2283G>T p.K761N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60694644; called by muse, mutect2, varscan2
- EPHB1 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.669); catalogued as COSV67654177; called by muse, mutect2, varscan2
- ETV4 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 17/376 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV60043670; called by muse, mutect2
- EVPL | c.3439G>T p.G1147W | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV56910405; called by muse, mutect2, varscan2
- EXOC5 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV61772148, COSV61772509; called by muse, mutect2, varscan2
- EXTL1 | c.1520T>A p.V507E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65332418; called by muse, mutect2, varscan2
- EYA4 | c.1150G>A p.E384K (on ENST00000531901 / NM_001301013.1; = p.E378K on NM_004100.5) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62046648; called by muse, mutect2
- FAM171A1 | c.2201G>A p.G734E | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV65315927; called by muse, mutect2
- FAM214A | c.1492C>G p.P498A | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs1201728745, COSV55927794; called by muse, mutect2
- FAT2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1259896022, COSV55832327; called by muse, mutect2
- FAT4 | c.4763C>T p.S1588L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs745581464; called by muse, mutect2, varscan2
- FTSJ1 | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV50025654; called by muse, mutect2, varscan2
- FZD8 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV65967681; called by muse, mutect2
- GCDH | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1333480915, COSV53434825; called by muse, mutect2, varscan2
- GFRAL | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs761253451; called by muse, mutect2, varscan2
- GOT1L1 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs1179328579; called by muse, mutect2, varscan2
- GPAM | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100788429; called by muse, mutect2
- GPM6A | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV54550058; called by muse, mutect2, varscan2
- GRIK5 | c.1489G>A p.V497M | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs764545491, COSV53484346; called by muse, mutect2, varscan2
- GRIN2D | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV54377459, COSV54381005; called by muse, mutect2
- GSK3B | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV51772486; called by muse, mutect2, varscan2
- GTF2E1 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV52202991; called by muse, mutect2, varscan2
- GUSB | c.1874G>C p.R625T | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372550726; called by muse, mutect2
- H3C2 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); catalogued as COSV52517864, COSV52519480; called by muse, mutect2
- HDHD3 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs1336274748; called by muse, mutect2, varscan2
- HEATR6 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV51745807; called by muse, mutect2
- HLA-DRA | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs745789724; called by muse, mutect2, varscan2
- HR | c.2769G>T p.W923C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as rs767109447; called by mutect2, varscan2
- HRNR | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs1208407617; called by muse, mutect2, varscan2
- HSPA8 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as COSV99914667; called by muse, mutect2, varscan2
- IGHV3-13 | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as rs564815380; called by muse, mutect2, varscan2
- IGSF10 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV56782110; called by muse, mutect2
- IMPG1 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV64059122; called by muse, mutect2, varscan2
- IPCEF1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.1); catalogued as COSV99500398; called by muse, mutect2
- IRS4 | c.1589G>C p.R530P | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as COSV64533634; called by muse, mutect2, varscan2
- ITGA1 | c.3287C>G p.S1096* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as rs752835656; called by muse, mutect2, varscan2
- JAM2 | c.572C>A p.T191K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.623); catalogued as COSV57256698; called by muse, mutect2, varscan2
- KCNA4 | c.926T>G p.I309R | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100068455, COSV60252130; called by muse, mutect2, varscan2
- KCNH7 | c.2735A>T p.D912V | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs761614087; called by muse, mutect2, varscan2
- KDM5A | c.4231C>T p.Q1411* | Nonsense Mutation (SNP) | VAF 5/74 reads (7%) | catalogued as COSV66996483; called by muse, mutect2
- KIF2B | c.828C>A p.N276K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52130429; called by muse, mutect2, varscan2
- KIF2B | c.1477C>A p.P493T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99275166; called by muse, mutect2
- KIF4B | c.881C>A p.T294N | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70528762; called by muse, mutect2
- KIR2DL1 | c.924C>A p.C308* | Nonsense Mutation (SNP) | VAF 37/860 reads (4%) | catalogued as COSV52412738; called by muse, mutect2
- KIR3DL1 | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 196/832 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1235353592, COSV58487824; called by muse, varscan2
- KLHL24 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as COSV99664932; called by muse, mutect2, varscan2
- KLHL3 | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59053906; called by muse, mutect2, varscan2
- KLK4 | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs774713282; called by muse, mutect2, varscan2
- LCP1 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59943248; called by muse, mutect2, varscan2
- LENG1 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.169); catalogued as rs1242502347; called by muse, mutect2, varscan2
- LENG8 | c.760G>C p.A254P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.237); catalogued as COSV58730693; called by muse, mutect2, varscan2
- LPAR5 | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276462186, COSV61692697; called by muse, mutect2, varscan2
- LRP1B | c.6310G>T p.A2104S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV67187374; called by muse, mutect2, varscan2
- LRP1B | c.6045G>T p.W2015C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67218117; called by muse, mutect2, varscan2
- LRP2 | c.12645G>A p.M4215I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55566230; called by muse, mutect2
- MAGEA11 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV60754543; called by muse, mutect2, varscan2
- MAP1A | c.6134del p.P2045Qfs*25 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as COSV55810773; called by mutect2, varscan2
- MAST4 | c.5247G>C p.Q1749H (on ENST00000403625 / NM_001164664.2; = p.Q1560H on NM_015183.3) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as rs895483902; called by muse, mutect2, varscan2
- MATN3 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as rs1227825418; called by muse, mutect2
- MATR3 | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99072662; called by muse, mutect2
- MCC | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs957272304, COSV56726946, COSV56732343; called by muse, mutect2
- MCM3AP | c.5512G>T p.E1838* | Nonsense Mutation (SNP) | VAF 21/221 reads (10%) | catalogued as COSV99387016; called by muse, mutect2
- MDC1 | c.3355C>A p.P1119T | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV64525242; called by muse, mutect2
- METTL27 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1434060859; called by muse, varscan2
- MMP16 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54149717, COSV54171640; called by muse, mutect2
- MNDA | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 21/327 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV63741392; called by muse, mutect2
- MRE11 | c.708C>G p.D236E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV60577202; called by muse, mutect2, varscan2
- MROH9 | c.1421G>A p.W474* | Nonsense Mutation (SNP) | VAF 55/209 reads (26%) | catalogued as COSV100882921; called by muse, mutect2, varscan2
- MTBP | c.297G>C p.E99D | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV59962346; called by muse, mutect2, varscan2
- MTMR3 | c.2924C>G p.S975C | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV100070982; called by muse, mutect2, varscan2
- MTX2 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 97/271 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV50888701; called by muse, mutect2, varscan2
- MYH4 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563253512; called by muse, mutect2, varscan2
- MYLK3 | c.1619C>A p.P540Q | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV101189046; called by muse, mutect2, varscan2
- MYO18B | c.2239G>T p.A747S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs1314024167; called by muse, mutect2, varscan2
- MYO1E | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV99895176; called by muse, mutect2, varscan2
- NCAPH | c.1828G>C p.G610R | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.059); catalogued as COSV53638883; called by muse, mutect2
- NDST1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV55791384; called by muse, mutect2
- NEB | c.9169G>A p.D3057N | Missense Mutation (SNP) | VAF 15/432 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51078040; called by muse, mutect2
- NEIL3 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99221005; called by muse, mutect2, varscan2
- NFE2L2 | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960111, COSV67960209, COSV67962392; called by muse, mutect2, varscan2
- NLRP11 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.442); catalogued as rs1447762001, COSV64086501; called by muse, mutect2, varscan2
- NLRP12 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219702752, COSV60755763; called by muse, varscan2
- NLRP12 | c.792G>T p.M264I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs1320950736; called by muse, mutect2, varscan2
- NLRP13 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100738237, COSV100738685; called by muse, mutect2, varscan2
- NLRP3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); catalogued as rs778304232, COSV60226409, COSV60228660; called by muse, mutect2, varscan2
- NTF3 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1417380268; called by muse, mutect2, varscan2
- NUP107 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV57496173, COSV57497254; called by muse, mutect2
- OLA1 | c.570A>T p.K190N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.077); catalogued as rs1362200627; called by muse, mutect2, varscan2
- OR13G1 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62943667; called by muse, mutect2, varscan2
- OR1C1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs187263571; called by muse, mutect2, varscan2
- OR1S1 | c.209C>A p.T70N | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs201590844, COSV58706814; called by muse, mutect2, varscan2
- OR2M5 | c.906G>T p.R302S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100822761, COSV63546198; called by muse, mutect2, varscan2
- OR2T12 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs756475129; called by muse, mutect2, varscan2
- OR52R1 | c.947del p.*316delext*? | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | catalogued as COSV61887208; called by mutect2, pindel, varscan2
- OR56A1 | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV57364083; called by muse, mutect2, varscan2
- OR6S1 | c.266C>G p.S89* | Nonsense Mutation (SNP) | VAF 21/213 reads (10%) | catalogued as rs1046909885; called by muse, mutect2
- OR8U1 | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as rs1430960262, COSV56415742; called by muse, mutect2, varscan2
- OSBPL10 | c.1361G>C p.R454T | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67338374; called by muse, mutect2
- OTUD7B | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64916305; called by muse, mutect2, varscan2
- PANX3 | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99421564; called by muse, mutect2, varscan2
- PARP3 | c.302G>T p.W101L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1452507037; called by muse, mutect2, varscan2
- PBX3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1355974210; called by muse, mutect2, varscan2
- PCDH15 | c.5791G>A p.E1931K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV57267062; called by muse, mutect2, varscan2
- PCDHA6 | c.134T>A p.V45E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554131106; called by muse, mutect2, varscan2
- PCDHB3 | c.2233C>A p.L745M | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554272698; called by muse, mutect2, varscan2
- PCDHB4 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV52020964; called by muse, mutect2, varscan2
- PCDHB6 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 96/226 reads (42%) | catalogued as COSV50694084, COSV50742999; called by muse, mutect2, varscan2
- PCDHGA10 | c.1906C>A p.L636M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV99545697; called by muse, mutect2
- PCDHGA3 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53972237, COSV54018156; called by muse, mutect2
- PCDHGC3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452697214, COSV52744109; called by muse, mutect2, varscan2
- PCED1B | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 95/171 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101423626; called by muse, mutect2, varscan2
- PIBF1 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100411266; called by muse, mutect2, varscan2
- PIGR | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100732671; called by muse, mutect2
- PIK3C2G | c.2628C>G p.I876M (on ENST00000676171; = p.I835M on NM_004570.5) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV56830671; called by muse, mutect2, varscan2
- PLB1 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1294057902; called by muse, mutect2, varscan2
- PLCE1 | c.2421-1G>T p.X807_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as rs1214286021, COSV99594325; called by mutect2, varscan2
- PODXL | c.1187G>A p.G396D (on ENST00000378555 / NM_001018111.3; = p.G364D on NM_005397.4) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs1254379387; called by muse, mutect2, varscan2
- POTEE | c.2705C>A p.T902N | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as rs775426284; called by muse, mutect2, varscan2
- PPP1R12C | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1244950046, COSV54736047; called by muse, mutect2, varscan2
- PRLR | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51492810; called by muse, mutect2
- PRRC2A | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1421060507; called by muse, mutect2
- PSG2 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 60/401 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as rs1371082043, COSV68885192; called by muse, mutect2, varscan2
- PTPN13 | c.2143C>T p.Q715* | Nonsense Mutation (SNP) | VAF 43/225 reads (19%) | catalogued as rs763013489; called by muse, mutect2, varscan2
- PTPRD | c.3245C>T p.S1082L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV61941028; called by muse, mutect2, varscan2
- PTPRD | c.1638C>G p.N546K | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.033); catalogued as COSV61968332; called by muse, mutect2, varscan2
- PXDNL | c.3206C>A p.A1069D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV62477564; called by muse, mutect2, varscan2
- QRSL1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1046948359; called by muse, mutect2
- RAPGEFL1 | c.1004C>A p.S335* | Nonsense Mutation (SNP) | VAF 13/249 reads (5%) | catalogued as COSV52862614; called by muse, mutect2
- RNF157 | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); catalogued as rs188246806; called by muse, mutect2, varscan2
- RNF43 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs750460220, COSV101348478; called by muse, mutect2, varscan2
- ROBO4 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1275432599; called by muse, mutect2, varscan2
- RPL6 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs1280267843; called by muse, mutect2
- RPS6KA2 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55826267, COSV99692157; called by mutect2, varscan2
- RSPRY1 | c.1703G>C p.R568T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV68028664; called by muse, mutect2
- RUSC1 | c.767G>A p.W256* | Nonsense Mutation (SNP) | VAF 180/418 reads (43%) | catalogued as COSV99430372; called by muse, mutect2, varscan2
- SAMD7 | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV59420645; called by muse, mutect2, varscan2
- SAMD9L | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV59084610; called by muse, mutect2
- SCAF11 | c.3016G>A p.D1006N | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs766886408; called by muse, mutect2
- SEMA3A | c.453+1G>T p.X151_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | catalogued as rs1334397880; called by muse, mutect2, varscan2
- SI | c.1635C>A p.C545* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV52286669; called by muse, mutect2, varscan2
- SIGLEC10 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs776499845; called by muse, mutect2, varscan2
- SIGLEC5 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.217); catalogued as rs770007074; called by muse, mutect2, varscan2
- SIK2 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as rs1378163924, COSV59253959; called by mutect2, varscan2
- SKIDA1 | c.99C>A p.F33L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV71610896; called by muse, mutect2, varscan2
- SLC10A2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs267603746, COSV55357572, COSV55361692; called by muse, mutect2, varscan2
- SLC16A6 | c.1037G>A p.G346E | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.422); catalogued as COSV59177693; called by muse, mutect2
- SLC1A6 | c.1353C>G p.I451M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99693926; called by muse, mutect2, varscan2
- SLC38A1 | c.1416G>T p.L472F | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.998); catalogued as rs1447213282, COSV67064973; called by muse, mutect2, varscan2
- SLC6A2 | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275882571; called by muse, mutect2, varscan2
- SLC9A4 | c.837G>T p.L279F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs866889679; called by muse, mutect2, varscan2
- SLCO1A2 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs1343895588, COSV56610312; called by muse, mutect2, varscan2
- SLCO6A1 | c.76C>G p.R26G | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.088); catalogued as rs1213480734, COSV101134332; called by muse, mutect2, varscan2
- SLIT3 | c.4491C>A p.Y1497* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV60594744; called by muse, mutect2, varscan2
- SLITRK6 | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV68389789; called by muse, mutect2
- SMYD5 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 10/194 reads (5%) | catalogued as COSV50265496; called by muse, mutect2
- SORCS2 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs35727450; called by muse, mutect2, varscan2
- SPATA18 | c.1079C>A p.S360* | Nonsense Mutation (SNP) | VAF 39/175 reads (22%) | catalogued as COSV54643648; called by muse, mutect2, varscan2
- SPTA1 | c.2531G>A p.S844N | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs777215763; called by muse, mutect2, varscan2
- SRRM2 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 85/503 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs559774892; called by muse, mutect2, varscan2
- SUGP1 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.118); catalogued as rs1394494957, COSV55924636; called by muse, mutect2, varscan2
- SV2B | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV57702886; called by muse, mutect2, varscan2
- SYNE2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV58359048; called by muse, mutect2
- SYNE2 | c.1818G>T p.K606N | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV59967069; called by muse, mutect2
- SYNE2 | c.1988C>G p.S663* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100648236, COSV59953939; called by muse, mutect2, varscan2
- SYNE2 | c.4491C>G p.F1497L | Missense Mutation (SNP) | VAF 51/492 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59957009; called by muse, mutect2, varscan2
- TAAR6 | c.812G>T p.W271L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51583747; called by muse, mutect2
- TAS2R16 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.295); catalogued as COSV50796913, COSV50797018; called by muse, mutect2, varscan2
- TCHH | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); catalogued as rs1200172563, COSV64273147, COSV64274723; called by muse, mutect2
- TFE3 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59948340; called by muse, mutect2, varscan2
- TIPARP | c.1194G>C p.E398D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs746549290; called by muse, mutect2, varscan2
- TMEM132D | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs534868390; called by muse, mutect2, varscan2
- TMOD1 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.844); catalogued as rs759813492, COSV52252103; called by muse, varscan2
- TMTC4 | c.1265G>T p.C422F (on ENST00000376234 / NM_001350577.2; = p.C441F on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs753924333; called by muse, mutect2
- TNC | c.5862G>T p.K1954N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.639); catalogued as COSV60789632; called by muse, mutect2, varscan2
- TP63 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53207041; called by muse, mutect2
- TPH2 | c.1236C>G p.I412M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV61591774; called by muse, mutect2, varscan2
- TRAV17 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.178); catalogued as rs780338637; called by muse, mutect2, varscan2
- TRIM49 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100316156; called by muse, mutect2
- TTLL5 | c.2042C>G p.S681C | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54034361; called by muse, mutect2
- TTN | c.67150G>T p.E22384* (on ENST00000591111; = p.E14960* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV60311026; called by muse, mutect2, varscan2
- TTN | c.59536G>A p.E19846K (on ENST00000591111; = p.E12422K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/204 reads (4%) | PolyPhen possibly damaging (0.819); catalogued as rs1485546407, COSV60361227; called by muse, mutect2
- TTN | c.26962C>G p.R8988G (on ENST00000591111; = p.R8061G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | PolyPhen benign (0.011); catalogued as COSV60118500; called by muse, mutect2, varscan2
- TYR | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750027827, CM091274; called by muse, mutect2
- UNK | c.1133G>C p.S378T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as rs1391684655; called by muse, mutect2, varscan2
- USH2A | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs375779739; called by muse, mutect2
- USP28 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 32/372 reads (9%) | catalogued as COSV50208915; called by muse, mutect2
- USP34 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV101276993; called by muse, mutect2, varscan2
- USP6 | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as rs1159208593; called by muse, mutect2, varscan2
- VDAC3 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.4); catalogued as rs902385263; called by muse, mutect2, varscan2
- VPS37C | c.264G>T p.L88= | Splice Region (SNP) | VAF 25/57 reads (44%) | catalogued as rs1399055143; called by muse, mutect2, varscan2
- WDFY2 | c.420G>T p.W140C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1399241850; called by muse, mutect2, varscan2
- WWTR1 | c.801G>T p.M267I | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1387317716, COSV62293288; called by muse, mutect2, varscan2
- XIRP2 | c.7899C>A p.S2633R (on ENST00000628543; = p.S2808R on NM_152381.6) | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772842255, COSV54738086; called by muse, mutect2, varscan2
- XRN1 | c.2836C>T p.H946Y | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.424); catalogued as COSV53809740; called by muse, mutect2
- XXYLT1 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367727409; called by muse, mutect2, varscan2
- YEATS2 | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100527498; called by muse, mutect2, varscan2
- ZEB2 | c.2002G>T p.E668* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV57951447; called by muse, mutect2, varscan2
- ZFHX3 | c.5114C>T p.S1705L | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV51732379, COSV51742716; called by muse, mutect2
- ZFHX4 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs765332040; called by muse, mutect2, varscan2
- ZMIZ2 | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99536440; called by muse, mutect2, varscan2
- ZMPSTE24 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.363); catalogued as CM058052, COSV65639750; called by muse, mutect2, varscan2
- ZNF160 | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1450473894; called by muse, mutect2, varscan2
- ZNF23 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.915); catalogued as rs1170593378, COSV100612037, COSV100612185; called by muse, mutect2, varscan2
- ZNF25 | c.1272G>T p.K424N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56921988; called by muse, mutect2, varscan2
- ZNF257 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV71306223; called by muse, mutect2, varscan2
- ZNF462 | c.4146G>A p.W1382* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV52939756; called by muse, mutect2, varscan2
- ZNF536 | c.3130C>G p.Q1044E | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as COSV62831590; called by muse, mutect2, varscan2
- ZNF569 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as COSV57596300, COSV57597519; called by muse, mutect2, varscan2
- ZNF578 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs1426544959; called by muse, mutect2, varscan2
- ZNF606 | c.1658C>G p.S553* | Nonsense Mutation (SNP) | VAF 7/91 reads (8%) | catalogued as COSV58705305; called by muse, mutect2
- ZNF606 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as rs1337218210; called by muse, mutect2, varscan2
- ZNF70 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | catalogued as rs145985311; called by muse, mutect2
- ZNF831 | c.4945A>T p.R1649W | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750556952; called by muse, mutect2
- ZPLD1 | c.964G>T p.G322W (on ENST00000466937 / NM_001329788.1; = p.G338W on NM_175056.2) | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs1399034898; called by muse, mutect2, varscan2
- ZPLD1 | c.1165C>A p.L389I (on ENST00000466937 / NM_001329788.1; = p.L405I on NM_175056.2) | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.129); catalogued as COSV60354287; called by muse, mutect2
- AADACL3 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AASDH | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA13 | c.4105C>G p.Q1369E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABCC12 | c.2308G>C p.E770Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ABLIM3 | c.1730-1G>T p.X577_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- ACACA | c.3208C>G p.Q1070E | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ACP7 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2
- ADAM17 | c.853_856del p.L285Sfs*6 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- ADAM21 | c.1850A>T p.K617M | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, varscan2
- ADAM21 | c.1987C>A p.Q663K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- ADAM22 | c.1673G>A p.W558* | Nonsense Mutation (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- ADAM29 | c.1996_1997insA p.P666Hfs*4 | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- ADAMTS12 | c.1793C>G p.S598* | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.1572G>T p.Q524H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- ADCY5 | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ADCY6 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- ADCY7 | c.374A>T p.Q125L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ADCY8 | c.2006A>T p.K669M | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- AGO2 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKAP4 | c.1618C>A p.L540M | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP6 | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ALPK1 | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- AMELY | c.227T>A p.L76Q (on ENST00000383036 / NM_001364814.1; = p.L62Q on NM_001143.1) | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKAR | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- ANKRD13A | c.1197C>G p.I399M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ANKRD17 | c.4346C>T p.A1449V | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ANKRD30A | c.1106C>A p.S369Y (on ENST00000611781; = p.S313Y on NM_052997.2) | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ANTXR1 | c.1242G>C p.K414N | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- AP2B1 | c.2681C>A p.T894N | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); called by muse, mutect2
- AP5M1 | c.1089-1G>C p.X363_splice | Splice Site (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- APBB1IP | c.721G>T p.V241F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOB | c.12839C>T p.A4280V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- APOB | c.7719G>T p.W2573C | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- APOB | c.7344G>T p.Q2448H | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- AQP9 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- AQR | c.2241C>T p.F747= | Splice Region (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.999G>T p.M333I (on ENST00000409202 / NM_001007231.3; = p.M325I on NM_014882.3) | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- ARHGAP25 | c.1825A>T p.I609F (on ENST00000409202 / NM_001007231.3; = p.I601F on NM_014882.3) | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ARHGAP5 | c.3575A>C p.H1192P | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ARHGEF17 | c.2789G>A p.S930N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ARHGEF26 | c.1158G>C p.K386N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF7 | c.918-2A>C p.X306_splice (on ENST00000375741 / NM_001113511.2; = p.X128_splice on NM_003899.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- ARMC4 | c.309C>G p.S103R | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ASAP1 | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- ASMTL | c.342G>T p.L114F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ASTN2 | c.1231C>A p.L411M (on ENST00000313400 / NM_001365069.1; = p.L360M on NM_014010.5) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ATL2 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ATP1B4 | c.913-2A>T p.X305_splice (on ENST00000218008 / NM_001142447.3; = p.X301_splice on NM_012069.5) | Splice Site (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- ATP2B1 | c.2974A>T p.K992* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- ATP8B1 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- ATP8B2 | c.3064G>A p.D1022N (on ENST00000672630; = p.D989N on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN2L | c.2063G>C p.R688P | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- AZIN1 | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCORL1 | c.3340C>G p.L1114V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- BIRC6 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- BRS3 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD11 | c.3162G>A p.M1054I (on ENST00000280758 / NM_001018072.2; = p.M591I on NM_001017523.2) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- C14orf28 | c.696G>A p.W232* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- C4orf33 | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2
- CABIN1 | c.1684A>T p.R562* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2
- CABIN1 | c.3763G>C p.E1255Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CACNG5 | c.577G>C p.G193R | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACYBP | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2
- CAMK4 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CAPS2 | c.1641T>G p.C547W | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CCDC38 | c.788C>G p.S263* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- CCDC65 | c.1384C>G p.Q462E | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- CCDC68 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CCDC88A | c.4765G>A p.D1589N (on ENST00000436346 / NM_001365480.1; = p.D1561N on NM_018084.5) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.218); called by muse, mutect2
- CCDC89 | c.719A>T p.H240L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CCDC97 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 36/478 reads (8%) | called by muse, mutect2
- CCN2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CCN4 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCNA2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CDC37 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.178); called by muse, mutect2
- CDC42BPB | c.775G>T p.G259W | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP162 | c.2810G>C p.R937T | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP43 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP70 | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- CFAP74 | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.6); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CFHR1 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CHD9 | c.4132G>T p.D1378Y | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLASP2 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CLCN1 | c.604G>T p.V202F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CLPX | c.1315C>A p.L439I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CLTC | c.1049G>C p.R350T | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CNOT1 | c.1889G>C p.G630A | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- COG3 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- COL11A1 | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- COL19A1 | c.1159C>A p.P387T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- COL5A3 | c.1816C>A p.P606T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CR1 | c.5691G>T p.W1897C | Missense Mutation (SNP) | VAF 123/312 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTNNA2 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTNNBL1 | c.977A>T p.N326I | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- CUL9 | c.6870G>C p.E2290D | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYP3A7 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- DAXX | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCC | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DCSTAMP | c.108C>A p.C36* | Nonsense Mutation (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- DDX60 | c.4210A>T p.R1404* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- DENND4C | c.2089G>C p.D697H | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); called by muse, mutect2
- DGKH | c.2873C>A p.S958Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- DHX29 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- DMXL1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH2 | c.9991G>A p.E3331K | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2
- DNAH8 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DNMBP | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2
- DNMT3A | c.2668G>T p.G890C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNMT3A | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- DOP1B | c.5663C>T p.S1888L | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2
- DST | c.5770G>T p.A1924S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, mutect2
- DTWD2 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- ECHDC1 | c.435-2A>G p.X145_splice (on ENST00000531967 / NM_001139510.1; = p.X122_splice on NM_018479.3) | Splice Site (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- EGF | c.3026G>T p.G1009V | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EGFLAM | c.242T>A p.L81Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- EHMT1 | c.1465C>G p.L489V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by muse, mutect2
- EIF2AK2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- EIF4A2 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- EIF4B | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ELL2 | c.1392G>C p.K464N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ELL2 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2
- EXO1 | c.2161A>C p.K721Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EXOSC3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- EXPH5 | c.5263C>T p.P1755S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- EXTL1 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- EYA2 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- F11 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83F | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FARSA | c.942G>A p.W314* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- FCRL5 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- FLT4 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FMNL2 | c.1115T>A p.L372Q | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FRMD4B | c.1521T>A p.F507L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); called by muse, mutect2
- FSHR | c.426T>A p.H142Q | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA3 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRB1 | c.676A>T p.T226S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRE | c.1104G>C p.Q368H | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNT2 | c.1084del p.R362Gfs*76 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | called by mutect2, varscan2
- GAPDHS | c.243T>A p.N81K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GAS7 | c.935A>T p.K312M (on ENST00000432992 / NM_201433.2; = p.K172M on NM_003644.3) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GCNT4 | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLS | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNA11 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); called by muse, mutect2
- GNG11 | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GNGT2 | c.104A>C p.E35A | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2
- GON4L | c.6443C>G p.S2148C | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GON4L | c.5840C>T p.S1947L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GON4L | c.2283G>T p.Q761H | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- GPC4 | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR6 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA2 | c.2458C>A p.L820I | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK1 | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRM1 | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM5 | c.1548G>C p.E516D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRM8 | c.2542A>T p.N848Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HEATR4 | c.2909G>A p.S970N | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2
- HERC4 | c.819G>T p.Q273H | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HGF | c.1121T>A p.V374D | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- HKDC1 | c.1723G>C p.D575H | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HNRNPH1 | c.121C>G p.Q41E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.04); called by muse, mutect2
- HOXB3 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HOXC13 | c.856A>T p.T286S | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- HPX | c.182T>A p.L61Q | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTR7 | c.1075A>T p.S359C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IFIT5 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- IGHV3-64 | c.23G>T p.W8L | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IGKV1-12 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2
- IGKV1D-43 | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- IL2 | c.308G>T p.R103M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- IL27 | c.306C>A p.D102E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2
- IMPG1 | c.993A>T p.E331D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS4 | c.1512G>A p.W504* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- INVS | c.1766G>A p.R589K | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2
- IPO8 | c.2750C>G p.S917* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- ITGA3 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ITGA3 | c.1424C>G p.P475R | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- ITPRID2 | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- IVNS1ABP | c.1060A>T p.M354L | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- JMY | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JPH1 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KCNA3 | c.1458C>A p.F486L | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNB2 | c.1065T>G p.F355L | Missense Mutation (SNP) | VAF 97/195 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- KCNH4 | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2
- KCNJ2 | c.385T>A p.F129I | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK2 | c.753G>T p.W251C (on ENST00000444842 / NM_001017425.3; = p.W236C on NM_014217.4) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KDM3B | c.3736G>T p.V1246L | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2
- KDM5C | c.4447C>T p.R1483W | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- KEAP1 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1109 | c.7765C>T p.Q2589* | Nonsense Mutation (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- KIAA2026 | c.3949C>T p.Q1317* | Nonsense Mutation (SNP) | VAF 29/209 reads (14%) | called by muse, mutect2, varscan2
- KIFC1 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLK1 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- KLK15 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KPNA6 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT40 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); called by muse, mutect2
- KRTAP10-4 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.141); called by muse, varscan2
- KRTAP13-3 | c.167G>C p.C56S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, varscan2
- KRTAP13-3 | c.76T>A p.C26S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, varscan2
- KRTAP22-1 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 24/134 reads (18%) | PolyPhen probably damaging (0.936); called by muse, varscan2
- KRTAP27-1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KTN1 | c.3529C>G p.Q1177E (on ENST00000395314 / NM_001271014.2; = p.Q1148E on NM_004986.4) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KYNU | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- LGR5 | c.1551A>T p.Q517H | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, varscan2
- LHPP | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.865); called by muse, mutect2
- LIG1 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.099); called by muse, mutect2
- LINGO1 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- LMX1A | c.1149A>G p.*383Wext*4 | Nonstop Mutation (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- LRFN2 | c.713G>C p.S238T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- LRP1B | c.6046G>T p.G2016* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- LRP2 | c.3940A>T p.S1314C | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- LRTM1 | c.680A>C p.E227A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- LUZP1 | c.2002C>T p.L668F | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LUZP4 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- LVRN | c.2378G>T p.W793L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- LVRN | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MAGEA11 | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MAGEC1 | c.613T>A p.S205T | Missense Mutation (SNP) | VAF 49/318 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- MAP3K12 | c.2140-1G>C p.X714_splice | Splice Site (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- MAP3K5 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MDGA1 | c.2285G>C p.G762A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); called by muse, mutect2
- MED7 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MEGF10 | c.2783C>G p.P928R | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- MICAL2 | c.2105A>T p.E702V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- MIDEAS | c.1736A>T p.D579V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- MIGA1 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- MMP16 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MNS1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2
- MPHOSPH10 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- MRC1 | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 47/183 reads (26%) | called by muse, mutect2, varscan2
- MROH2B | c.4165G>T p.V1389L | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- MROH9 | c.1236C>A p.Y412* | Nonsense Mutation (SNP) | VAF 70/130 reads (54%) | called by muse, mutect2, varscan2
- MRPS9 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- MSH2 | c.1387-2A>T p.X463_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- MTERF2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MTMR12 | c.1840G>C p.D614H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2
- MTMR4 | c.2865G>C p.Q955H | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.438); called by muse, mutect2
- MTMR8 | c.1646G>A p.C549Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MUC16 | c.2006A>T p.K669M | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, varscan2
- MUC16 | c.1894G>T p.A632S | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); called by muse, varscan2
- MUC16 | c.1468T>G p.S490A | Missense Mutation (SNP) | VAF 124/285 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- MYH15 | c.1741G>C p.D581H | Missense Mutation (SNP) | VAF 57/390 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYH4 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MYH8 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- MYO1H | c.1329G>T p.E443D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- MYO1H | c.1876G>T p.G626W | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO3B | c.2256G>C p.Q752H | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYPN | c.2620G>A p.D874N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- NEDD1 | c.1179G>T p.Q393H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- NEPRO | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NEU1 | c.519G>C p.W173C | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); called by muse, mutect2
- NFRKB | c.2390C>G p.S797C (on ENST00000446488 / NM_001143835.2; = p.S822C on NM_006165.3) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- NIM1K | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- NIPBL | c.7709C>G p.S2570C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- NLRC4 | c.1544A>T p.H515L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NLRP12 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP2 | c.342A>C p.E114D | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.033); called by muse, mutect2
- NLRP2 | c.3151T>A p.W1051R | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP5 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.205); called by muse, mutect2
- NMU | c.428G>C p.R143T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2
- NOC2L | c.377G>C p.G126A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NOC3L | c.2365C>G p.L789V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NPAT | c.479C>A p.P160Q | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- NPC1L1 | c.3344C>A p.P1115Q | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NXPH2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- OBSCN | c.14945A>T p.H4982L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OLFM4 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- OPRK1 | c.1108C>A p.L370M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10X1 | c.947G>C p.R316T | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR11H4 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- OR13C9 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- OR1L3 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR2T1 | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2T11 | c.818C>G p.A273G | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- OR2T27 | c.207G>T p.R69S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T34 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.443); called by muse, mutect2
- OR4C11 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR4Q3 | c.86G>T p.W29L | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2
- OR6F1 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR6V1 | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8B12 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OSBPL9 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PARP4 | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PASK | c.2003A>T p.Q668L | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- PATZ1 | c.1702C>T p.L568F | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDH10 | c.2119G>T p.G707C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PCDHA6 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PCDHB12 | c.1082C>A p.P361Q | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.057); called by muse, mutect2
- PCDHB6 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, varscan2
- PDCD11 | c.3535C>T p.P1179S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- PDE7B | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PDZD9 | c.299G>C p.G100A (on ENST00000424898 / NM_001363519.1; = p.G40A on NM_173806.4) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PEX10 | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGBD4 | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.296); called by muse, mutect2
- PHF19 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2
- PHKA2 | c.1569+1G>T p.X523_splice | Splice Site (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- PI4KA | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- PIGX | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIK3CD | c.2506A>T p.N836Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PKD1L1 | c.1692G>T p.W564C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- PKD1L2 | c.1588C>A p.L530M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- PKHD1L1 | c.5063C>G p.S1688C | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- PKHD1L1 | c.9886G>T p.A3296S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PKP4 | c.2455G>C p.E819Q | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PLA2G4E | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PLEKHA5 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- POFUT1 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- POLR1B | c.2363G>C p.G788A | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.703); called by muse, mutect2
- POMT1 | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- POSTN | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PPIL1 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- PPL | c.5041G>C p.D1681H | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PPM1E | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPP2R1B | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRDM16 | c.3358G>A p.E1120K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- PRDM9 | c.2511T>A p.C837* | Nonsense Mutation (SNP) | VAF 55/207 reads (27%) | called by muse, mutect2, varscan2
- PRMT8 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PROSER1 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSPH | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PTPN13 | c.6199G>A p.E2067K (on ENST00000411767 / NM_080683.3; = p.E2048K on NM_006264.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2
- PTPN20 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 25/560 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- PTPRB | c.1173G>T p.M391I | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RABL2B | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2
- RAD1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- RAI14 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RANBP17 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- RANBP3 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RBM17 | c.450A>T p.R150S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM23 | c.481G>C p.E161Q (on ENST00000359890 / NM_001077351.2; = p.E145Q on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RBP3 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHCE | c.1153+1G>T p.X385_splice | Splice Site (SNP) | VAF 28/105 reads (27%) | called by muse, mutect2, varscan2
- RHOBTB3 | c.397G>T p.V133F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- RIPPLY2 | c.198del p.A67Qfs*34 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- RNF19A | c.2209G>C p.E737Q | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); called by muse, mutect2
- RUBCNL | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2
- RYR1 | c.4451G>T p.S1484I | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- RYR3 | c.10160A>T p.E3387V (on ENST00000389232; = p.E3388V on NM_001036.6) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- SALL1 | c.2714T>A p.V905E | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- SAMD4A | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- SCAF11 | c.3014T>C p.L1005P | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- SCEL | c.630G>C p.Q210H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SCN10A | c.2353G>A p.G785R | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SCN7A | c.3178A>T p.N1060Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SEPTIN9 | c.122C>G p.S41C (on ENST00000427177 / NM_001113491.2; = p.S23C on NM_006640.4) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SERPINC1 | c.155T>A p.M52K | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFSWAP | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.617); called by muse, mutect2
- SGK1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH3GL2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SHANK2 | c.5431G>A p.E1811K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SHBG | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- SIMC1 | c.1519G>T p.A507S (on ENST00000443967 / NM_001308196.1; = p.A92S on NM_198567.5) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SKAP1 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- SLC2A13 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2
- SLC4A5 | c.1905C>A p.F635L | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC4A8 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 27/344 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2
- SLC6A4 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A5 | c.1788G>C p.K596N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLC7A9 | c.896A>T p.Y299F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SLC9A2 | c.1874C>T p.T625I | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.133); called by muse, mutect2
- SMARCC2 | c.2436G>C p.K812N | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2
- SNAI2 | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX4 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- SORCS1 | c.1267G>T p.V423L | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- SOS1 | c.1790G>C p.G597A | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- SP7 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- SPATA31E1 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SPHKAP | c.3071A>T p.E1024V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPON1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- SPSB2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SPTBN1 | c.1922G>A p.W641* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- SREBF2 | c.653G>C p.G218A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SRGAP2 | c.1954G>C p.E652Q (on ENST00000624873 / NM_001170637.4; = p.E653Q on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ST6GAL2 | c.1450C>A p.P484T | Missense Mutation (SNP) | VAF 26/58 reads (45%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST6GALNAC1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 12/161 reads (7%) | PolyPhen benign (0); called by muse, mutect2
- ST7L | c.749T>A p.I250N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- STK4 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STXBP5L | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.978); called by muse, varscan2
- SVIL | c.1910G>T p.R637L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SYNE1 | c.18574G>C p.G6192R (on ENST00000367255 / NM_182961.4; = p.G6121R on NM_033071.3) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- SYNE2 | c.1819A>C p.K607Q | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- SYNGAP1 | c.2818G>C p.G940R | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.543); called by muse, mutect2
- TACC2 | c.4354C>G p.L1452V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TAOK2 | c.1124C>G p.S375* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- TAP2 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- TBCA | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TBX15 | c.689G>T p.G230V (on ENST00000369429 / NM_001330677.2; = p.G124V on NM_152380.3) | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRD6 | c.3653A>T p.N1218I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TENM2 | c.4855T>C p.Y1619H (on ENST00000518659 / NM_001122679.2; = p.Y1380H on NM_001080428.3) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TENT5A | c.943C>G p.Q315E | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- TESPA1 | c.625G>A p.E209K (on ENST00000316577 / NM_001098815.3; = p.E71K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TEX14 | c.3353C>T p.A1118V (on ENST00000240361 / NM_001201457.2; = p.A1072V on NM_031272.5) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TFAP2B | c.837dup p.G280Wfs*42 | Frame Shift Ins (INS) | VAF 12/106 reads (11%) | called by mutect2, varscan2
- TFG | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- TG | c.6815C>T p.S2272F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- THAP12 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- THBS2 | c.2098T>A p.W700R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIMD4 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TINAG | c.121G>T p.V41F | Missense Mutation (SNP) | VAF 147/395 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TMCC1 | c.1365G>C p.Q455H (on ENST00000393238 / NM_001349268.2; = p.Q131H on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMEM131 | c.5603G>A p.R1868K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- TMEM132D | c.2098C>A p.L700M | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM184C | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2
- TMEM236 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM38B | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM68 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNC | c.2639T>A p.M880K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- TOR1A | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2
- TPCN1 | c.1293C>G p.F431L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TRHR | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- TRIM8 | c.571-2A>G p.X191_splice | Splice Site (SNP) | VAF 52/300 reads (17%) | called by muse, mutect2, varscan2
- TRPC4 | c.2386C>T p.L796F (on ENST00000379705 / NM_016179.4; = p.L801F on NM_003306.3) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- TRPC4 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TRPC7 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TRPM4 | c.2938C>T p.Q980* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- TSC2 | c.544A>T p.N182Y | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSC22D1 | c.1181C>G p.S394* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- TSEN34 | c.447G>C p.E149D | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- TSGA10IP | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSN | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 40/598 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TSPYL5 | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TTC31 | c.941G>T p.S314I | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TTN | c.94207G>A p.A31403T (on ENST00000591111; = p.A23979T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/274 reads (4%) | PolyPhen benign (0.015); called by muse, mutect2
- TTN | c.71068G>C p.D23690H (on ENST00000591111; = p.D16266H on NM_003319.4) | Missense Mutation (SNP) | VAF 7/125 reads (6%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TUBB2A | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TXK | c.72-1G>C p.X24_splice | Splice Site (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- UBQLN3 | c.140A>T p.K47M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC5B | c.1067-2A>T p.X356_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- UNC79 | c.6255C>G p.I2085M (on ENST00000393151 / NM_001346218.2; = p.I1908M on NM_020818.5) | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2
- USP25 | c.2294C>G p.S765* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- USP29 | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- USP30 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- USP38 | c.2481_2498del p.G828_S833del | In Frame Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel
- USP54 | c.2367G>T p.R789S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- VN1R2 | c.655T>A p.F219I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- VWA3B | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 66/482 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- WASF1 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- WDFY3 | c.8596+1G>T p.X2866_splice | Splice Site (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- WDR49 | c.1487C>T p.S496F (on ENST00000308378 / NM_001366158.1; = p.S837F on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- WDR64 | c.1325G>C p.R442T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- WFDC3 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.052); called by muse, mutect2
- YIPF5 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZC3H13 | c.2431A>T p.R811W | Missense Mutation (SNP) | VAF 52/678 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZFP2 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZFP36 | c.358G>A p.E120K (on ENST00000594442; = p.E114K on NM_003407.5) | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFR | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZFYVE26 | c.4967G>A p.G1656E | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFYVE26 | c.4225G>T p.A1409S | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ZIK1 | c.58A>T p.M20L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- ZIM2 | c.1402T>A p.C468S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ZNF12 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF223 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- ZNF223 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
281 further variants in this file (13 protein-altering or splice-affecting, 242 silent, 26 other) are not listed here.
